Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A4Z1, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A4Z1-01A (Primary Tumor).

Department of Cancer Pathology

Gender: F

Examination result

Clinical diagnosis (suspicion): **ca mammae dex**

ICD-O-3
carcinoma, infiltrating lobular, NOS 8520/3
Site: breast, NOS C50.9
hw
11/4/12

Material:

1) Material: right breast with tumour (+possibly with AXILLARY LYMPH NODES DEPENDING ON THE EXAM. RESULT).
Method of collection: Breast with no lymph nodes (mastectomy simplex)

Histopathological Diagnosis:

Including test No. _

Invasive lobular carcinoma and lobular carcinoma in situ of the right breast. (NHG2, pT1c, pN 0 (sn)). (8520/3

Macroscopic description:

Right breast, sized 20.4 x 13.8 x 4.6 cm, removed without armpit tissues and with a skin flap of 19.4 x 8.6 cm. Weight 540 g.

Tumour sized 1.6 x 1.4 x 1.6 cm in the inner lower quadrant, placed 2.1 cm from the lower edge, 1.6 cm from the base and 0.9 cm from the skin.

Microscopic description:

Invasive lobular carcinoma - NHG2 (3+2+1/0 mitoses/10 HPF - visual area 0.55 mm) and lobular carcinoma in situ with nuclear atypia < 10% of the tumour).

Glandular tissue showing fibrocytoid lesions adenosis, usual ductal hyperplasia, fibroadenoma.

Invasive lesions removed 1.6 cm from the base.

Assistant:

Result of immunohistochemical examination

Estrogen receptors found in 75% of neoplastic cell nuclei.

Progesterone receptors found in 10-75% of neoplastic cell nuclei.

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.

Negative reaction in invasive cancerous cells (Score = 1+). The expression of proliferating cell nuclear antigen Ki 67 in 10% cellular nuclei.

Assistant:

CONTACT YOUR DOCTOR WITH THIS

IFAA Discrepancy		X
Dual/Synchronous Prim. Involvement		X

Source: NCI Genomic Data Commons file 0dcf5926-ae5f-4f36-aae7-c6a51ed1cf84 (TCGA-D8-A4Z1.D77DF136-6F63-48B7-8187-6F8F98CC1F44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).